Somatic mutation profile of tumor specimen TCGA-D7-6525-01A (aliquot TCGA-D7-6525-01A-11D-1800-08) from TCGA case TCGA-D7-6525, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.1 years (21,223 days).
Specimen TCGA-D7-6525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 593817ff-e082-4054-a5ea-3315b9d92f16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6525-10A (Blood Derived Normal), aliquot TCGA-D7-6525-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1aa62a8-2d38-4b89-b07c-a8d5410299c1

The open-access MAF lists 181 somatic variants for this specimen: 127 protein-altering or splice-affecting, 50 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 50, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 3, Intron 1, RNA 1, Splice Region 1, 3'UTR 1, 5'UTR 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3805T>G p.F1269V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs776975421, COSV67977883; called by muse, mutect2, varscan2
- ALPI | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs374647501, COSV55014564; called by muse, mutect2, varscan2
- AMPH | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs761049841, COSV57731874; called by muse, mutect2, varscan2
- ANKRD35 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553739131, COSV62909438; called by muse, mutect2
- AREL1 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV62665365; called by muse, mutect2, varscan2
- ARID2 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as COSV57595026; called by muse, mutect2, varscan2
- ATP11C | c.2113A>C p.T705P | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as COSV59559161; called by muse, mutect2, varscan2
- ATP2B3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs782779816, COSV54839830; called by muse, mutect2, varscan2
- ATRNL1 | c.2449A>C p.N817H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs782705608, COSV58072801; called by muse, mutect2, varscan2
- BARHL1 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778876265, COSV55036805; called by muse, mutect2
- BEND4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72468902; called by muse, mutect2, varscan2
- BICC1 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54061754; called by muse, mutect2, varscan2
- BRSK1 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs574851872, COSV58593031; called by muse, mutect2
- C1QL3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1211686082, COSV54348096; called by muse, mutect2, varscan2
- CAD | c.6254G>A p.R2085H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53023280; called by muse, mutect2, varscan2
- CCDC141 | c.3594A>C p.E1198D | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.412); catalogued as COSV55368289; called by muse, mutect2, varscan2
- CD44 | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53527941; called by muse, mutect2, varscan2
- CDC42EP3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs144011190, COSV54873242; called by muse, mutect2, varscan2
- CDK14 | c.737A>T p.Y246F (on ENST00000380050 / NM_001287135.2; = p.Y228F on NM_012395.3) | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV56023125; called by muse, mutect2, varscan2
- CHD2 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs759974626, COSV59118915; called by muse, mutect2, varscan2
- CMYA5 | c.7388G>T p.R2463I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV71404036; called by muse, mutect2, varscan2
- CPN1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs757656853, COSV64941891; called by muse, mutect2, varscan2
- CUX2 | c.3601C>A p.L1201I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV55623405; called by muse, mutect2, varscan2
- DKK4 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55182014; called by muse, mutect2
- DNAH5 | c.6551T>A p.V2184E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs200805455, COSV54202341; called by muse, mutect2, varscan2
- DNAJB6 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1282245966, COSV51094150; called by muse, mutect2, varscan2
- DUS1L | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs138475537; called by muse, mutect2
- EDNRA | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV60095469, COSV60099076; called by muse, mutect2, varscan2
- EIF5B | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56810859; called by muse, mutect2, varscan2
- EPB42 | c.1913G>A p.R638K (on ENST00000441366 / NM_001114134.2; = p.R668K on NM_000119.3) | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV55748432; called by muse, mutect2
- ERICH3 | c.4222T>G p.L1408V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV58598591; called by muse, mutect2, varscan2
- ETV3L | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV71900932; called by muse, mutect2, varscan2
- FAM76B | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62556012; called by muse, mutect2
- FBN2 | c.7282C>T p.P2428S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV52490989; called by muse, mutect2, varscan2
- FBXO34 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV58253175; called by muse, mutect2, varscan2
- FILIP1L | c.955C>T p.Q319* (on ENST00000354552 / NM_182909.3; = p.Q79* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | catalogued as COSV58764535, COSV58771472; called by muse, mutect2, varscan2
- GANC | c.2465A>G p.Q822R | Missense Mutation (SNP) | VAF 25/118 reads (21%) | PolyPhen benign (0.001); catalogued as COSV58807063; called by muse, mutect2, varscan2
- GAPDH | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.879); catalogued as COSV57520378; called by muse, mutect2, varscan2
- GPAT2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746013914, COSV64002969; called by muse, mutect2, varscan2
- GPR141 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV57731223, COSV57732088; called by muse, mutect2, varscan2
- HMMR | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62373659; called by muse, mutect2, varscan2
- IFT140 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755177677, COSV101276598; called by mutect2, varscan2
- IGHV1-2 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs557034159; called by muse, mutect2, varscan2
- IKBIP | c.626del p.N209Ifs*3 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs752553685; called by mutect2, pindel, varscan2
- IQGAP1 | c.4526C>T p.T1509I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51581265; called by muse, mutect2, varscan2
- KCNA1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66836428; called by muse, mutect2, varscan2
- KDM5B | c.2017-1G>C p.X673_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV52503684; called by muse, mutect2
- KIRREL1 | c.757T>G p.L253V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV63285139; called by muse, mutect2, varscan2
- L3MBTL4 | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53112343; called by muse, mutect2, varscan2
- LILRA1 | c.1099dup p.L367Pfs*11 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | catalogued as rs766823529; called by mutect2, pindel, varscan2
- LIMCH1 | c.1351A>C p.T451P | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58272687; called by muse, mutect2
- LIN7A | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV54017493, COSV99691577, COSV99691982; called by muse, mutect2, varscan2
- LINC01098 | n.624A>G | Splice Region (SNP) | VAF 28/95 reads (29%) | catalogued as rs576040952; called by muse, mutect2, varscan2
- LIPI | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60707652; called by muse, mutect2, varscan2
- MAP2 | c.1218A>C p.K406N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV52280220; called by muse, mutect2, varscan2
- MCPH1 | c.1911G>T p.L637F | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV60909717, COSV60915682; called by muse, mutect2, varscan2
- MED16 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.712); catalogued as rs199831785; called by muse, mutect2, varscan2
- MSN | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.871); catalogued as COSV64303093; called by muse, mutect2, varscan2
- MUC16 | c.21171G>T p.K7057N | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as COSV67442532, COSV67470602; called by muse, mutect2, varscan2
- NAV3 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs759179498, COSV57060090; called by muse, mutect2, varscan2
- NBEA | c.8623C>A p.Q2875K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59758119; called by muse, mutect2, varscan2
- NECTIN2 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373335144; called by muse, mutect2, varscan2
- NELL1 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as COSV54236708, COSV54263958; called by muse, mutect2, varscan2
- NIPBL | c.5076G>A p.M1692I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56941498; called by muse, mutect2, varscan2
- NOP56 | c.1446_1448del p.K484del | In Frame Del (DEL) | VAF 115/299 reads (38%) | catalogued as rs754160900; called by pindel, varscan2
- NUP153 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1203524259, COSV50446083; called by muse, mutect2, varscan2
- NXN | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV61093716; called by muse, mutect2, varscan2
- OPCML | c.1036T>C p.*346Rext*1 | Nonstop Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs1246333214, COSV59402163; called by muse, mutect2, varscan2
- OR2G2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs760919741, COSV60739255; called by muse, mutect2, varscan2
- OR51M1 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV60783711; called by muse, mutect2, varscan2
- OR8B4 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62069125; called by muse, mutect2, varscan2
- OR8H3 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57907307; called by muse, mutect2, varscan2
- PAX1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV68271012; called by muse, mutect2, varscan2
- PCDHA1 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs782576028, COSV65372482; called by muse, mutect2, varscan2
- PCDHB12 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.079); catalogued as rs782361618, COSV53398854, COSV53402211; called by muse, mutect2, varscan2
- PCNA | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV64770270; called by muse, mutect2, varscan2
- PEG3 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV55623864; called by muse, mutect2, varscan2
- PHACTR4 | c.1760G>C p.R587P (on ENST00000373839 / NM_001350159.2; = p.R597P on NM_023923.4) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65783076, COSV65784818; called by muse, mutect2, varscan2
- PIGG | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs765531884, COSV56316035; called by muse, mutect2, varscan2
- PLEKHN1 | c.1798G>A p.A600T (on ENST00000379409; = p.A548T on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs375248247; called by muse, mutect2
- PON1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55930452, COSV55930550; called by muse, mutect2
- PRR27 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60640082; called by muse, mutect2, varscan2
- PSD3 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs182238334, COSV58961489, COSV58973631; called by muse, mutect2, varscan2
- PTPRH | c.3162G>C p.K1054N | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54742348, COSV54750132; called by muse, mutect2, varscan2
- PUM2 | c.349-2A>G p.X117_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV57577549; called by muse, mutect2, varscan2
- PXDN | c.886T>G p.L296V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV53225843; called by muse, mutect2, varscan2
- PXDNL | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV62477066; called by muse, mutect2, varscan2
- RAG1 | c.25T>G p.L9V | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs771932715, COSV55023827; called by muse, mutect2, varscan2
- RLBP1 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51527160; called by muse, mutect2, varscan2
- SCN9A | c.1796G>A p.S599N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as COSV57599233; called by muse, mutect2, varscan2
- SDC4 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs901163167, COSV65594977; called by muse, mutect2, varscan2
- SFMBT1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV56251657; called by muse, mutect2, varscan2
- SLIT2 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56558833; called by muse, mutect2, varscan2
- SLITRK5 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61520618; called by muse, mutect2, varscan2
- SOX1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1566475451, COSV58378226; called by muse, mutect2, varscan2
- ST8SIA1 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV53950122; called by muse, mutect2, varscan2
- TAF15 | c.617G>A p.R206H (on ENST00000605844 / NM_139215.3; = p.R203H on NM_003487.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1268378138; called by muse, mutect2, varscan2
- TCEA1 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV67172012; called by muse, mutect2, varscan2
- TMEM132D | c.1962G>T p.K654N | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV67158618; called by muse, mutect2, varscan2
- TMEM200A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1416618515, COSV51648874; called by muse, mutect2, varscan2
- TMX1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV63335449; called by muse, mutect2, varscan2
- TP53BP1 | c.5291-2A>G p.X1764_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53017596; called by muse, mutect2, varscan2
- TRAK1 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59638806; called by muse, mutect2, varscan2
- TRIM42 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761016638, COSV53880065; called by muse, mutect2, varscan2
- TRIM9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762640179, COSV53612436; called by muse, mutect2, varscan2
- TRO | c.3287A>T p.N1096I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV51497141; called by muse, mutect2, varscan2
- TRPC3 | c.614G>A p.R205H (on ENST00000379645 / NM_001366479.2; = p.R132H on NM_003305.2) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1469309386, COSV53371540; called by muse, mutect2, varscan2
- TTN | c.2061A>C p.Q687H (on ENST00000591111; = p.Q641H on NM_003319.4) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | PolyPhen benign (0); catalogued as rs188680791, COSV59871041; called by muse, mutect2, varscan2
- TYR | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54469491; called by muse, mutect2, varscan2
- UGT2B28 | c.264T>A p.N88K | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV59430406; called by muse, mutect2
- USP6NL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs575447541, COSV53208897, COSV99509533; called by muse, mutect2, varscan2
- VPS13B | c.6587G>A p.S2196N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as rs751998053, COSV62132251; called by muse, mutect2, varscan2
- WFS1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs143084511, CM015265, COSV56987285; called by muse, mutect2, varscan2
- XYLT1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs773329278, COSV54476465; called by muse, mutect2, varscan2
- ZCCHC14 | c.931C>T p.H311Y (on ENST00000268616; = p.H448Y on NM_015144.3) | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1424193124, COSV51883369; called by muse, mutect2, varscan2
- ZNF107 | c.1712A>G p.K571R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV61326638, COSV61328994; called by muse, mutect2, varscan2
- ZNF34 | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV100603332, COSV58638152; called by muse, mutect2, varscan2
- ZNF347 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1471694812, COSV61967522; called by muse, mutect2, varscan2
- ZNF439 | c.335A>C p.K112T | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.843); catalogued as COSV58308352; called by muse, mutect2, varscan2
- ZNF585B | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.119); catalogued as COSV100459609; called by muse, mutect2, varscan2
- ADAMTS1 | c.1395C>A p.D465E | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDC73 | c.431_432del p.E144Vfs*5 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | called by pindel, varscan2
- GOLGA3 | c.3517del p.V1174Sfs*8 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- MROH5 | c.773del p.F258Sfs*2 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- ZNF559-ZNF177 | c.110del p.N37Ifs*6 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.3420C>A p.G1140= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV54435029; called by muse, mutect2, varscan2
- ARHGAP28 | c.696G>C p.G232= (on ENST00000383472 / NM_001366230.1; = p.G73= on NM_001010000.3) | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV51630979, COSV51637108; called by muse, mutect2, varscan2
- BEND5 | c.1077C>T p.P359= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV65716325; called by muse, mutect2, varscan2
- CES1 | c.417C>A p.I139= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs771909303, COSV62085229; called by muse, mutect2, varscan2
- CHST1 | c.828C>T p.C276= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV57321601; called by muse, mutect2, varscan2
- CNTN6 | c.2133A>G p.G711= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV63160959; called by muse, mutect2, varscan2
- DCC | c.4251C>A p.A1417= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV71425060; called by muse, mutect2, varscan2
- DLC1 | c.303A>G p.E101= | Silent (SNP) | VAF 102/319 reads (32%) | catalogued as COSV52288970; called by muse, mutect2, varscan2
- DNAH7 | c.9951C>T p.A3317= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs532655291, COSV56750830; called by muse, mutect2, varscan2
- DRD2 | c.141C>A p.V47= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV60753904; called by muse, mutect2, varscan2
- EFNB3 | c.393G>T p.S131= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs201844534, COSV56832711, COSV56834991; called by muse, mutect2, varscan2
- ETV6 | c.609C>G p.S203= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as COSV101122792, COSV67148064; called by muse, mutect2, varscan2
- FARSB | c.1191T>G p.T397= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV56047989; called by muse, mutect2, varscan2
- FASN | c.6087G>T p.A2029= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV60750251; called by muse, mutect2, varscan2
- GFI1 | c.963C>T p.F321= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV54041378; called by muse, mutect2, varscan2
- GFPT1 | c.1821G>A p.V607= (on ENST00000357308 / NM_001244710.2; = p.V589= on NM_002056.4) | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV61946406; called by muse, mutect2, varscan2
- GRXCR1 | c.60C>T p.I20= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as rs267600162, COSV67669835; called by muse, mutect2, varscan2
- HOXC6 | c.447G>A p.S149= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs1280656905, COSV54536114, COSV54536198; called by muse, mutect2, varscan2
- HSPH1 | c.618A>G p.S206= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV60710009; called by muse, mutect2, varscan2
- IPO5 | c.1167C>T p.C389= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1227265904, COSV55151940; called by muse, mutect2, varscan2
- KCTD19 | c.2358G>A p.T786= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs757212801, COSV58570978; called by muse, mutect2, varscan2
- LRRC4C | c.930G>T p.L310= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV53417467; called by muse, mutect2, varscan2
- MARK3 | c.1197G>A p.Q399= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV53505975; called by muse, mutect2, varscan2
- MDH1B | c.522A>G p.E174= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100982356, COSV65588444, COSV65588826; called by muse, mutect2, varscan2
- MYH9 | c.3777C>A p.V1259= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV53381692; called by muse, mutect2, varscan2
- OR2G3 | c.279T>C p.T93= | Silent (SNP) | VAF 67/268 reads (25%) | catalogued as COSV60680716, COSV60681025; called by muse, mutect2, varscan2
- OR2M4 | c.591A>G p.R197= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV60707120; called by muse, mutect2, varscan2
- OR4A47 | c.345G>T p.V115= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV71444830, COSV71444930; called by muse, mutect2, varscan2
- OR9Q2 | c.801C>A p.S267= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV61111283; called by muse, mutect2
- OTOF | c.4599C>T p.I1533= (on ENST00000272371 / NM_194248.3; = p.I766= on NM_004802.4) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV55494930; called by muse, mutect2, varscan2
- PCDH11X | c.2397G>A p.E799= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV53439542; called by muse, mutect2, varscan2
- PCDHA13 | c.1716C>T p.S572= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV56475554; called by muse, mutect2, varscan2
- PRRG3 | c.288C>G p.A96= | Silent (SNP) | VAF 62/106 reads (58%) | catalogued as COSV64850665; called by muse, mutect2, varscan2
- PTCH2 | c.2034G>T p.P678= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100941866, COSV64709571; called by muse, mutect2, varscan2
- PXDN | c.3339C>A p.G1113= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53225835; called by muse, mutect2, varscan2
- RBFOX1 | c.801C>T p.Y267= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs747421844, COSV60944179; called by muse, varscan2
- RHOT2 | c.348G>A p.V116= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs753430450, COSV53466154; called by muse, mutect2, varscan2
- SACS | c.12831T>C p.P4277= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV66533510; called by muse, mutect2, varscan2
- SCN8A | c.1530G>A p.G510= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61976035; called by muse, mutect2, varscan2
- SEMA6D | c.825T>G p.T275= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV60372243; called by muse, mutect2, varscan2
- SLC5A2 | c.1215C>T p.F405= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV57890012; called by muse, mutect2, varscan2
- SNRPD3 | c.84T>C p.Y28= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV53182538; called by muse, mutect2, varscan2
- SPHKAP | c.4293T>C p.I1431= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs952364970, COSV60867832; called by muse, mutect2, varscan2
- TMPRSS15 | c.1155T>C p.T385= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV53034369, COSV99516712; called by muse, mutect2, varscan2
- TRPC4 | c.1875A>G p.Q625= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV58989542; called by muse, mutect2, varscan2
- UNC5D | c.357T>C p.T119= | Silent (SNP) | VAF 7/191 reads (4%) | catalogued as COSV54767319; called by muse, mutect2
- VWA3A | c.1059C>T p.H353= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs200987727, COSV55387682; called by muse, mutect2, varscan2
- YPEL1 | c.225C>T p.A75= | Silent (SNP) | VAF 36/241 reads (15%) | catalogued as rs774758879, COSV58604592; called by muse, mutect2, varscan2
- ZFPM2 | c.45G>T p.P15= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV101343524, COSV68274572; called by muse, mutect2
- ZNF470 | c.1071T>C p.H357= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV57967481; called by muse, mutect2, varscan2
- ACSL5 | c.-65C>T | 5'UTR (SNP) | VAF 33/106 reads (31%) | catalogued as COSV100634756; called by muse, mutect2, varscan2
- CPLANE1 | c.*3634A>G | 3'UTR (SNP) | VAF 19/65 reads (29%) | catalogued as COSV57051089; called by muse, mutect2, varscan2
- DCHS2 | n.3046C>T | RNA (SNP) | VAF 34/110 reads (31%) | catalogued as rs774677154, COSV59717808; called by muse, mutect2, varscan2
- SCN3A | c.603-144C>G | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99326710, COSV99328261; called by muse, mutect2, varscan2
